Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAHZ, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAHZ-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 3.3 cm; no rete testis available; no angio-invasion; no invasion of tunica albuginea; epididymis free of tumor; surgical margin of spermatic cord free of tumor.

Date of procurement (= date of orchidectomy):

ICD-O-3
Seminoma NOS 9061/3
Site: R Testis NOS C62.9
9x5 5/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file e6d8aa1e-0f17-4da9-b9aa-66958b55c0f1 (TCGA-2G-AAHZ-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).